Somatic mutation profile of tumor specimen TARGET-50-PALLCK-01A (aliquot TARGET-50-PALLCK-01A-01D) from TARGET case TARGET-50-PALLCK, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 2.7 years (994 days).
Specimen TARGET-50-PALLCK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d34d317d-2b21-4278-8fd4-961694ebbd21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PALLCK-10A (Blood Derived Normal), aliquot TARGET-50-PALLCK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3627a643-94c9-47e6-a46a-0b6cb9e1d082

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 10, Silent 6, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 47/50 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDHR3 | c.1316C>A p.P439H | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58414472; called by muse, mutect2, varscan2
- HNRNPM | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- KCNC2 | c.862G>T p.V288L | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PCDH1 | c.2986G>C p.D996H | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RTCB | c.251G>C p.G84A | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.312); called by muse, mutect2
- SUN3 | c.745A>C p.T249P | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.305); called by muse, mutect2
- TTN | c.10933G>C p.V3645L (on ENST00000591111; = p.V3599L on NM_003319.4) | Missense Mutation (SNP) | VAF 22/108 reads (20%) | called by muse, mutect2, varscan2
- TYR | c.1262A>T p.N421I | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- XPO5 | c.3246dup p.H1083Afs*38 | Frame Shift Ins (INS) | VAF 9/13 reads (69%) | called by mutect2, pindel, varscan2
- ZNF837 | c.1451T>C p.F484S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- KCNH2 | c.477C>T p.R159= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs1271822540; ClinVar: likely benign; called by muse, mutect2
- LRRC71 | c.651C>T p.A217= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV100503886; called by muse, mutect2, varscan2
- NAV3 | c.2760G>A p.K920= | Silent (SNP) | VAF 66/114 reads (58%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.207G>A p.E69= | Silent (SNP) | VAF 94/130 reads (72%) | called by muse, varscan2
- PTGER2 | c.447G>C p.S149= | Silent (SNP) | VAF 45/48 reads (94%) | called by muse, mutect2, varscan2
- TNFRSF11B | c.1200C>T p.C400= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV52070227; called by muse, mutect2
